CCDI case PBCPBW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/f3637334-f3e4-4aab-a7fd-c596f3b06554

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 10.8 years (3,949 days).

Biospecimens (3 samples)
- Sample 0DWRMB: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWRMV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DWRMZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
